Somatic mutation profile of tumor specimen TARGET-40-PAKXLD-01A (aliquot TARGET-40-PAKXLD-01A-01D) from TARGET case TARGET-40-PAKXLD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 14.4 years (5,245 days).
Specimen TARGET-40-PAKXLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a19db6-bbbe-4f56-8d71-9b0d86b2581f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAKXLD-10A (Blood Derived Normal), aliquot TARGET-40-PAKXLD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e84a926-879c-4120-98a6-d3a32190d6e4

The open-access MAF lists 97 somatic variants for this specimen: 58 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 21, Intron 9, RNA 4, 5'UTR 2, 3'UTR 2, Splice Site 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 35/58 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs776623078; called by muse, mutect2, varscan2
- ALDH3A1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1228805609; called by muse, mutect2, varscan2
- ANPEP | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100262494; called by muse, mutect2, varscan2
- BICD1 | c.2903G>C p.C968S | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs201572851, COSV99863255; called by muse, mutect2, varscan2
- CCDC86 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374168203; called by muse, varscan2
- CCNB3 | c.884A>T p.K295M | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as COSV52070023; called by muse, mutect2, varscan2
- CELSR2 | c.6698G>A p.R2233Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs376451201; called by muse, mutect2, varscan2
- COL4A5 | c.2630C>A p.P877Q | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV100089980; called by muse, mutect2, varscan2
- DENND3 | c.269A>C p.Y90S | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52801331; called by muse, varscan2
- DNM2 | c.1088A>G p.N363S | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV58971509; called by muse, mutect2, varscan2
- IGKV3-20 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs202237525; called by muse, mutect2, varscan2
- KRT83 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs533080987; called by muse, mutect2, varscan2
- MTMR9 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1048178221; called by muse, mutect2, varscan2
- PCDHB2 | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.113); catalogued as COSV99164387; called by muse, mutect2, varscan2
- PTPRB | c.5747C>T p.A1916V | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.12); catalogued as rs1305981141; called by muse, mutect2, varscan2
- RBP3 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs781901493; called by muse, mutect2, varscan2
- SCML4 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as COSV64637724; called by muse, mutect2, varscan2
- SEC16A | c.1403A>G p.Q468R | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294996552; called by muse, mutect2, varscan2
- AP3B2 | c.2053T>C p.S685P | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2
- APBB1 | c.986T>A p.L329Q | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP25 | c.1636T>G p.S546A (on ENST00000409202 / NM_001007231.3; = p.S538A on NM_014882.3) | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ARHGAP35 | c.1361_1362dup p.A455Rfs*7 | Frame Shift Ins (INS) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.1125G>T p.Q375H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CCDC141 | c.366A>T p.R122S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- CD19 | c.907T>A p.C303S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CNOT1 | c.1387G>T p.V463F | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.021); called by muse, mutect2
- CRX | c.467C>A p.A156E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CSNK1G2 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2
- CXorf65 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH5 | c.8700T>G p.I2900M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2
- EBI3 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 62/394 reads (16%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3954G>T p.K1318N | Missense Mutation (SNP) | VAF 88/401 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FSIP2 | c.17530A>C p.I5844L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- GBP6 | c.281T>C p.V94A | Missense Mutation (SNP) | VAF 44/233 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HERC5 | c.2133+1G>T p.X711_splice | Splice Site (SNP) | VAF 10/92 reads (11%) | called by muse, varscan2
- IGKV2D-24 | c.175A>T p.S59C | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- IL1RAPL2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2
- KCNE4 | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- MICAL3 | c.4928A>T p.K1643M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- NCF2 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- NLRP4 | c.2972G>T p.R991M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2T11 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- OR5D14 | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PARD6B | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PPP1R7 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 71/250 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMD1 | c.2586G>T p.K862N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- PTPN14 | c.3164G>T p.G1055V | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYROXD1 | c.1396G>C p.D466H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, varscan2
- RABGEF1 | c.614G>T p.R205M (on ENST00000439720 / NM_001287061.2; = p.R192M on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- RYR3 | c.2662G>T p.G888C | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL4 | c.1258A>T p.T420S | Missense Mutation (SNP) | VAF 41/356 reads (12%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SEZ6L | c.2717A>G p.E906G | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A6 | c.1466G>T p.G489V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSPAN16 | c.139del p.L47Sfs*17 | Frame Shift Del (DEL) | VAF 54/245 reads (22%) | called by pindel, varscan2
- TTC25 | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBQLN4 | c.1196A>T p.N399I | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- ZNF317 | c.1346A>T p.D449V | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- CNOT1 | c.1386G>A p.E462= | Silent (SNP) | VAF 15/71 reads (21%) | called by muse, mutect2
- COPS7A | c.729G>A p.R243= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs1228036268; called by muse, mutect2, varscan2
- CRYM | c.570G>A p.S190= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs754359609, COSV54831585, COSV54831801; called by muse, mutect2, varscan2
- DNAH17 | c.603C>T p.S201= | Silent (SNP) | VAF 31/234 reads (13%) | called by muse, mutect2, varscan2
- DNAH3 | c.5130A>G p.G1710= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- DRP2 | c.543T>C p.P181= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- FARSA | c.1305G>A p.S435= | Silent (SNP) | VAF 51/391 reads (13%) | catalogued as rs369171062; called by muse, mutect2, varscan2
- FKBPL | c.648G>A p.R216= | Silent (SNP) | VAF 47/338 reads (14%) | called by muse, mutect2, varscan2
- GIPC2 | c.687A>C p.S229= | Silent (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2
- KCNE4 | c.639C>A p.S213= | Silent (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- NKAIN1 | c.279G>A p.R93= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV99744581; called by muse, mutect2, varscan2
- OR4C46 | c.108T>G p.T36= | Silent (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
- PRRC2B | c.2775C>T p.S925= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as rs763141063; called by muse, varscan2
- RIMS1 | c.3030T>C p.S1010= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- RREB1 | c.1131T>G p.P377= | Silent (SNP) | VAF 41/138 reads (30%) | catalogued as COSV100619503; called by muse, mutect2, varscan2
- SLC25A47 | c.378G>A p.Q126= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs1330329652; called by muse, mutect2
- SPATC1 | c.1371C>A p.I457= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2
- TMEM63C | c.2190A>T p.P730= | Silent (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- TNS2 | c.2082G>A p.E694= (on ENST00000314250 / NM_170754.4; = p.E704= on NM_015319.2) | Silent (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- USP24 | c.6949C>T p.L2317= | Silent (SNP) | VAF 36/253 reads (14%) | catalogued as rs1250403348; called by muse, mutect2, varscan2
- ZDBF2 | c.1989C>T p.S663= | Silent (SNP) | VAF 42/160 reads (26%) | catalogued as COSV100985017, COSV65628490; called by muse, mutect2, varscan2
- AC020558.3 | n.123G>C | RNA (SNP) | VAF 38/310 reads (12%) | called by muse, mutect2, varscan2
- AC022217.1 | chr5:172762519 G>A | 3'Flank (SNP) | VAF 26/260 reads (10%) | called by muse, mutect2
- ATG4B | c.539-25A>T | Intron (SNP) | VAF 21/99 reads (21%) | called by muse, mutect2, varscan2
- CARD11 | c.-62G>T | 5'UTR (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- CCDC17 | c.1388+9G>C | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- CHIAP2 | n.1492C>T | RNA (SNP) | VAF 24/125 reads (19%) | called by muse, mutect2, varscan2
- CLN3 | c.302+19G>A | Intron (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- CNNM3 | c.1921-56C>G | Intron (SNP) | VAF 24/87 reads (28%) | catalogued as rs1460895825; called by muse, mutect2, varscan2
- DAPK1 | c.1924-70G>T | Intron (SNP) | VAF 52/240 reads (22%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2158-10C>G | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- FAM205BP | n.2137C>A | RNA (SNP) | VAF 59/250 reads (24%) | called by muse, mutect2, varscan2
- LYZL6 | c.*101T>A | 3'UTR (SNP) | VAF 12/80 reads (15%) | called by muse, varscan2
- NARF | c.639+28A>G | Intron (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2
- NARF | c.639+29G>T | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- OR7E163P | n.587C>T | RNA (SNP) | VAF 4/34 reads (12%) | catalogued as rs1375708923; called by muse, mutect2
- SFTPD | c.433+132C>T | Intron (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- TMC5 | c.-51T>C | 5'UTR (SNP) | VAF 63/156 reads (40%) | called by muse, mutect2, varscan2
- TRO | c.*1T>G | 3'UTR (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2, varscan2
